CCDI case PBCDYU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/e83df66a-9756-4847-81e4-9aa2420987d9

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sex cord-gonadal stromal tumor, NOS: ICD-O-3 morphology code: 8590/1; Tissue or organ of origin: Ovary; Age at diagnosis: 14.9 years (5,454 days).

Biospecimens (3 samples)
- Sample 0DPSN4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPSND: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPSNP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
